Gene-level copy-number profile of tumor specimen TCGA-33-6737-01A from TCGA case TCGA-33-6737, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 71.3 years (26,033 days).
Specimen TCGA-33-6737-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0a884418-c64e-4b18-ae57-96a06372b598.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-33-6737-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b4cc66a-6f0e-4692-9525-91f0821d15b9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 1,008; copy number 2: 18,682; copy number 3: 27,983; copy number 4: 10,169; copy number 5: 74; copy number 6: 1,465; copy number 7: 334; copy number 8: 4; copy number 10: 5; copy number 11: 10; copy number 15: 12; copy number 17: 1; copy number 18: 2; copy number 19: 2; copy number 23: 14; copy number 25: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-33-6737-01): tumor purity 0.48, ploidy 2.99, whole-genome doublings 1 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,966,929–27,104,728, 46 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 386 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–2,331,664, 41 genes, copy number 7: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN, MYT1L, AC093390.2, AC093390.1, MYT1L-AS1.
- chr5:37,085,056–37,753,435, 12 genes, copy number 15 (within-gene range 4–15): RPS4XP6, CPLANE1, RBISP2, OFD1P17, RN7SL37P, AC025449.2, AC025449.1, NUP155, RNU7-75P, AC117532.1, WDR70, KCTD9P5.
- chr6:120,526,294–120,526,400, 1 gene, copy number 17: RNU6-214P.
- chr6:121,641,009–122,726,373, 15 genes, copy number 10–25 (within-gene range 4–25): AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1.
- chr6:123,216,339–125,980,244, 20 genes, copy number 11–23 (within-gene range 4–23): TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216.
- chr8:135,742,343–145,066,685, 226 genes, copy number 7 (broad region; genes not listed).
- chr10:4,786,629–4,962,568, 3 genes, copy number 7: AKR1E2, AKR1C6P, U8.
- chr12:81,257,975–81,759,553, 1 gene, copy number 7 (within-gene range 4–7): PPFIA2.
- chr12:81,378,042–89,353,271, 63 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:5,381,641–5,630,700, 4 genes, copy number 8: AP005671.1, EPB41L3, AP005059.2, AP005059.1.

Autosomal genes at a single copy (total copy number 1): 1,008. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
